Somatic mutation profile of tumor specimen TCGA-EB-A82B-01A (aliquot TCGA-EB-A82B-01A-11D-A34U-08) from TCGA case TCGA-EB-A82B, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.2 years (21,249 days).
Specimen TCGA-EB-A82B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cbff068-efc5-469c-a02b-fcd0cd11572b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A82B-10B (Blood Derived Normal), aliquot TCGA-EB-A82B-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a296a5a-f833-47a7-8c43-0764cd7a484c

The open-access MAF lists 53 somatic variants for this specimen: 35 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 17, Frame Shift Ins 3, Nonsense Mutation 3, Translation Start Site 1, Splice Region 1, In Frame Del 1, 3'UTR 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.5991G>A p.W1997* (on ENST00000358273 / NM_001042492.3; = p.W1976* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | catalogued as rs876660696, COSV62192659; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NF1 | c.6855C>G p.Y2285* (on ENST00000358273 / NM_001042492.3; = p.Y2264* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as rs772295894, CM972796, CM981382, COSV62214006, COSV62218349; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACTN3 | c.2581C>T p.L861F | Missense Mutation (SNP) | VAF 23/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100074237; called by muse, mutect2
- BCLAF3 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV100503278; called by muse, mutect2, varscan2
- CDK2 | c.624G>T p.E208D | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99906708; called by muse, mutect2, varscan2
- COPE | c.925T>G p.*309Gext*55 | Nonstop Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV99447402; called by muse, mutect2, varscan2
- DNAI2 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs762305426, COSV56758132, COSV56761840; called by muse, mutect2, varscan2
- DST | c.1798G>C p.E600Q (on ENST00000361203 / NM_001374722.1; = p.E274Q on NM_001723.6) | Missense Mutation (SNP) | VAF 40/527 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV99754769; called by muse, mutect2
- FHL5 | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | catalogued as COSV58738631; called by muse, mutect2
- HBP1 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 104/197 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.669); catalogued as COSV56017582; called by muse, mutect2, varscan2
- IGHM | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.04); catalogued as rs1555378356; called by muse, mutect2, varscan2
- KIR3DL1 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.922); catalogued as COSV100373009; called by muse, varscan2
- LCE3E | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/76 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen probably damaging (0.916); catalogued as COSV100909948; called by muse, mutect2, varscan2
- ME3 | c.1751A>G p.Y584C | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100660931; called by muse, mutect2, varscan2
- MYH6 | c.4160A>G p.E1387G | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100676481; called by muse, mutect2, varscan2
- MYOM2 | c.3097C>T p.R1033C | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770705626, COSV50795461; called by muse, mutect2
- OR4K5 | c.932T>C p.I311T | Missense Mutation (SNP) | VAF 15/350 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100262334; called by muse, mutect2
- OR4N2 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 31/410 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100269569; called by muse, mutect2
- PCDHA12 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.098); catalogued as COSV100249905; called by muse, mutect2, varscan2
- PDS5B | c.2170dup p.R724Pfs*16 | Frame Shift Ins (INS) | VAF 28/140 reads (20%) | catalogued as rs746601412; called by mutect2, varscan2
- PPP3CB | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV61151567; called by muse, mutect2, varscan2
- PSMD11 | c.644-1G>A p.X215_splice | Splice Site (SNP) | VAF 14/80 reads (18%) | catalogued as COSV99912427; called by muse, mutect2, varscan2
- SCN2A | c.4045C>G p.L1349V | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99331272, COSV99333663; called by muse, mutect2, varscan2
- SERPING1 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1363997186, CM083114, CM083115, COSV99557950; called by muse, mutect2, varscan2
- SLC5A11 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 62/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100762752, COSV61743884; called by muse, mutect2, varscan2
- SLC6A11 | c.1575G>A p.A525= | Splice Region (SNP) | VAF 10/72 reads (14%) | catalogued as rs1320790036, COSV99594405; called by mutect2, varscan2
- SLCO2B1 | c.1301G>A p.R434Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs773407118, COSV56937062; called by muse, mutect2, varscan2
- SMPD1 | c.1756T>C p.C586R | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100192637; called by muse, mutect2, varscan2
- SPTA1 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as COSV100934777, COSV63755231; called by muse, mutect2, varscan2
- TACC2 | c.6787G>A p.V2263I (on ENST00000334433; = p.V341I on NM_006997.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs187285591; called by muse, mutect2, varscan2
- TBX5 | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100091096; called by muse, mutect2
- TKTL2 | c.1808G>C p.S603T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV99761339; called by muse, mutect2, varscan2
- CAMK2A | c.763_765del p.N255del | In Frame Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- DMRT1 | c.628dup p.Y210Lfs*29 | Frame Shift Ins (INS) | VAF 23/98 reads (23%) | called by mutect2, pindel, varscan2
- RGS12 | c.3573dup p.E1192* | Frame Shift Ins (INS) | VAF 27/114 reads (24%) | called by mutect2, pindel, varscan2
- ACSM2B | c.1212C>T p.P404= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as rs367747928, COSV61656848; called by muse, mutect2, varscan2
- ALDH4A1 | c.636C>T p.F212= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1377758325, COSV99311822; called by muse, mutect2
- CDH4 | c.1396A>C p.R466= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100848721; called by muse, mutect2, varscan2
- CNTN3 | c.1356G>A p.E452= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV55181325, COSV99724142; called by muse, mutect2, varscan2
- DUSP4 | c.486G>A p.K162= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99529785; called by muse, mutect2, varscan2
- GLUL | c.456C>T p.N152= | Silent (SNP) | VAF 17/175 reads (10%) | catalogued as rs771286038, COSV59382157; called by muse, mutect2, varscan2
- IFFO1 | c.1407G>A p.R469= (on ENST00000396840 / NM_001330324.2; = p.R472= on NM_080730.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/288 reads (13%) | catalogued as COSV100351069; called by muse, varscan2
- IL22RA1 | c.1341G>A p.L447= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV99582947; called by muse, mutect2
- KRT20 | c.327C>T p.N109= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99391378; called by muse, mutect2, varscan2
- MYH9 | c.2028C>T p.H676= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as rs768833414, COSV99338617; called by muse, mutect2, varscan2
- PLCXD3 | c.822T>G p.P274= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100125618; called by muse, mutect2, varscan2
- SLITRK5 | c.366C>T p.T122= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as COSV61524466; called by muse, mutect2, varscan2
- TBX1 | c.786C>T p.T262= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV100226467; called by muse, mutect2, varscan2
- VWF | c.3636C>T p.V1212= | Silent (SNP) | VAF 80/243 reads (33%) | catalogued as COSV99778847; called by muse, mutect2, varscan2
- ZNF208 | c.2952A>G p.T984= | Silent (SNP) | VAF 4/86 reads (5%) | catalogued as rs1375720257, COSV68112501; called by muse, mutect2
- ZNF442 | c.690T>C p.T230= | Silent (SNP) | VAF 72/239 reads (30%) | catalogued as COSV99664338; called by muse, mutect2, varscan2
- ZSCAN5A | c.66G>T p.L22= | Silent (SNP) | VAF 15/92 reads (16%) | catalogued as COSV99570057; called by muse, mutect2, varscan2
- IL26 | c.*1A>G | 3'UTR (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99970876; called by muse, mutect2
